Somatic mutation profile of tumor specimen 0DDA7E from CCDI case PBBNMN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant tumor, spindle cell type; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 6.0 years (2,186 days).
Specimen 0DDA7E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c5877514-bfe3-4467-afea-f573b908c034.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDA73 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/554e1dcd-5b31-4c12-a311-c42f90ce3435

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 2, 3'UTR 1, Silent 1, Nonsense Mutation 1, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP13A2 | c.3442C>T p.R1148C | Missense Mutation (SNP) | VAF 82/280 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs759327218; called by muse, mutect2, varscan2
- CLDN5 | c.8C>T p.S3F (on ENST00000618236 / NM_001363066.2; = p.S88F on NM_003277.4) | Missense Mutation (SNP) | VAF 156/431 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1316754512; called by muse, mutect2, varscan2
- BLMH | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 58/644 reads (9%) | called by muse, mutect2
- CDC45 | c.52-7C>T | Splice Region (SNP) | VAF 198/614 reads (32%) | called by muse, mutect2, varscan2
- GOLGA8M | c.1873G>A p.A625T | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GIMAP7 | c.480C>T p.C160= | Silent (SNP) | VAF 34/643 reads (5%) | catalogued as rs1185221583, COSV100543602; called by muse, mutect2
- KIFC3 | c.-39-30C>T | Intron (SNP) | VAF 35/104 reads (34%) | called by muse, mutect2, varscan2
- POC5 | c.1584+77del | Intron (DEL) | VAF 4/25 reads (16%) | called by mutect2, varscan2
- UFD1 | c.-70G>T | 5'UTR (SNP) | VAF 136/436 reads (31%) | catalogued as rs941347131; called by muse, mutect2, varscan2
- WDR36 | c.*41G>A | 3'UTR (SNP) | VAF 6/104 reads (6%) | called by muse, mutect2
